Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4811, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4811-01A (Primary Tumor).

FINAL DIAGNOSIS

PART 1: KIDNEY, LEFT, NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CONVENTIONAL TYPE (CLEAR CELL), 6.0 CM IN GREATEST DIMENSION WITH THIRTY PERCENT (30%) NECROSIS, WITH FUHRMAN GRADING OF 3 / 4.
- B. MICROSCOPIC IMPLANT OF CARCINOMA (0.2 CM) IS PRESENT IN THE PERINEPHRIC ADIPOSE TISSUE.
- C. NO EXTENSION OF CARCINOMA INTO GEROTA'S FASCIA.
- D. NO ANGIOLYMPHATIC INVASION SEEN.
- E. ONE (1) LYMPH NODE FREE OF TUMOR.
- F. ADRENAL GLAND WITH NO SIGNIFICANT HISTOLOGIC CHANGE.
- G. TNM STAGE = T3 N0 MX.
- H.

PART 2: REGION OF LYMPH NODES, EXCISION -

THREE (3) LYMPH NODES FREE OF TUMOR ZERO/THREE) (0/3).

Final Diagnosis

BRONCHIAL WASHING:

SATISFACTORY FOR INTERPRETATION.

SUSPICIOUS FOR METASTATIC RENAL CELL CARCINOMA (SEE COMMENT).

Comment:

A few scattered large cells with low nuclear/cytoplasmic ratio, enlarged nuclei with nucleoli, and bubbly cytoplasm are present, and are suspicious for renal cell carcinoma, clear cell type. Despite the atypical features, these cells, in this context, cannot be definitively categorized as neoplastic without appropriate immunohistochemical confirmation. The very scant nature of the specimen precludes additional confirmatory diagnostic studies.

Source: NCI Genomic Data Commons file 5138b4da-cd88-43ae-876d-50558c454bea (TCGA-B0-4811.3757EF41-CDCA-4464-B6F3-1484CB2ECB94.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).